Gene-level copy-number profile of tumor specimen C3L-05262-02 (profiled together with C3L-05262-05) from CPTAC case C3L-05262, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 53.7 years (19,625 days).
Specimen C3L-05262-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6c2e7c9b-c828-4187-abae-b0eb00fb58b6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-05262-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,742 have no estimate.
https://portal.gdc.cancer.gov/files/d2d97c84-bfa0-4270-9b69-fa0b6eead5c8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 401; copy number 1: 5,931; copy number 2: 44,732; copy number 3: 4,725; copy number 4: 3,081; copy number 5: 10; copy number 6: 1.

Homozygous deletions (total copy number 0; autosomes only): 57 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:8,059,572–8,199,973, 1 gene (within-gene range 0–1): AC105233.4.
- chr8:8,154,308–8,226,614, 3 genes: ENPP7P1, FAM85B, AC068020.1.
- chr9:21,524,307–22,455,740, 20 genes (within-gene range 0–2): SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.
- chr9:61,581,813–61,642,494, 3 genes: AL935212.3, FAM242D, Y_RNA.
- chr9:64,369,394–64,498,745, 9 genes: ANKRD20A4P, RNU6-1193P, SNX18P9, CR769776.2, CYP4F25P, CR769776.1, CNN2P3, GXYLT1P6, AL773524.1.
- chr10:131,966,455–132,205,759, 7 genes: BNIP3, AL162274.2, AL162274.1, AL162274.3, JAKMIP3, AL512622.1, DPYSL4.
- chr10:132,419,083–133,145,304, 14 genes: AL451069.2, AL451069.3, LINC02870, AL451069.1, LINC01165, INPP5A, NKX6-2, CFAP46, LINC01166, LINC01167, LINC01168, ADGRA1, ADGRA1-AS1, RPL5P28.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,774,813–196,959,622, 5 genes, copy number 5–6 (within-gene range 4–6): CFHR3, CFHR1, BX248415.1, CFHR4, CFHR2.
- chr20:30,214,765–30,362,276, 6 genes, copy number 5: CFTRP3, LINC01597, AL121762.1, AL121762.2, Y_RNA, FAM242A.

Autosomal genes at a single copy (total copy number 1): 3,448. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
